Gene-level copy-number profile of tumor specimen TCGA-AH-6643-01A from TCGA case TCGA-AH-6643, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 50.0 years (18,273 days).
Specimen TCGA-AH-6643-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.ce12bb26-84fb-447c-bebf-f74734744c87.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AH-6643-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cc8d6525-851d-48c1-b28d-dbc147d7452b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 7; copy number 2: 14,963; copy number 3: 27,387; copy number 4: 12,760; copy number 5: 1,889; copy number 6: 2,604; copy number 7: 71; copy number 12: 106; copy number 13: 3; copy number 16: 7; copy number 20: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AH-6643-01A-11D-1825-01): tumor purity 0.75, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:185,950,469–186,695,287, 11 genes: AC097500.1, RPL21P32, LINC01473, AC104058.1, RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV, AC017101.1.
- chr11:127,406,028–127,408,148, 2 genes: RN7SKP121, RN7SKP279.
- chr16:7,004,007–7,004,112, 1 gene: RNU6-328P.
- chr20:15,021,553–15,022,958, 2 genes: RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 194 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:88,459,477–90,895,776, 106 genes, copy number 12 (broad region; genes not listed).
- chr15:91,099,950–91,605,873, 3 genes, copy number 13 (within-gene range 2–13): SV2B, AC123784.1, CRAT37.
- chr17:39,835,037–39,944,734, 7 genes, copy number 16: KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C.
- chr17:40,516,892–40,665,181, 7 genes, copy number 20: AC004585.1, CCR7, AC004585.2, SMARCE1, AC073508.2, AC073508.3, KRT222.
- chr17:66,197,693–68,763,882, 71 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
